Somatic mutation profile of tumor specimen TCGA-29-1711-01A (aliquot TCGA-29-1711-01A-01W-0633-09) from TCGA case TCGA-29-1711, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 45.1 years (16,485 days).
Specimen TCGA-29-1711-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95c9f1d6-44e6-439f-8a4c-5fd5266103cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1711-10A (Blood Derived Normal), aliquot TCGA-29-1711-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5352b40f-df55-43ab-bf2b-0385923b0aed

The open-access MAF lists 63 somatic variants for this specimen: 49 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 12, Frame Shift Del 6, In Frame Del 2, Splice Site 2, Nonsense Mutation 2, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 65/105 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA5 | c.4180C>G p.H1394D | Missense Mutation (SNP) | VAF 120/150 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67017756; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3620G>T p.R1207M | Missense Mutation (SNP) | VAF 188/289 reads (65%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.645); catalogued as COSV54457171; called by muse, mutect2, varscan2
- ADGRF5 | c.3779T>C p.L1260S | Missense Mutation (SNP) | VAF 66/133 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51936769; called by muse, mutect2, varscan2
- AKR1C4 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 61/167 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as rs531165422, COSV54122270; called by muse, mutect2, varscan2
- ALB | c.1109T>G p.L370R | Missense Mutation (SNP) | VAF 94/272 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99891189; called by muse, mutect2, varscan2
- ATG7 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 82/362 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV61614060; called by muse, mutect2, varscan2
- CBX8 | c.1053G>A p.W351* | Nonsense Mutation (SNP) | VAF 8/88 reads (9%) | catalogued as COSV99485826; called by muse, mutect2
- CDK12 | c.1958C>T p.P653L | Missense Mutation (SNP) | VAF 67/117 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV71001620, COSV71002694; called by muse, mutect2, varscan2
- CEP85L | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 70/115 reads (61%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as COSV100821153; called by muse, mutect2
- CLRN1 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 100/481 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58995361; called by muse, mutect2, varscan2
- CNOT11 | c.991G>T p.A331S | Missense Mutation (SNP) | VAF 82/215 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV56820467; called by muse, mutect2, varscan2
- CNR2 | c.589_612del p.F197_G204del | In Frame Del (DEL) | VAF 14/48 reads (29%) | catalogued as COSV65693528; called by mutect2, pindel, varscan2
- COL15A1 | c.1637G>C p.W546S | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV66647075; called by muse, mutect2, varscan2
- COL4A4 | c.62C>G p.T21R | Missense Mutation (SNP) | VAF 214/336 reads (64%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100306572; called by muse, mutect2
- DLG5 | c.3013_3052del p.K1005Gfs*109 | Frame Shift Del (DEL) | VAF 12/53 reads (23%) | catalogued as COSV64948737; called by mutect2, pindel
- DNAH12 | c.1236G>C p.E412D | Missense Mutation (SNP) | VAF 106/277 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV60857691; called by muse, mutect2, varscan2
- DNAH17 | c.5448C>A p.N1816K | Missense Mutation (SNP) | VAF 52/81 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV67758020, COSV67759196; called by muse, mutect2, varscan2
- EPM2A | c.688T>G p.W230G | Missense Mutation (SNP) | VAF 82/117 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV62296949; called by muse, mutect2, varscan2
- EXOC6B | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 359/817 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.259); catalogued as COSV55562445; called by muse, mutect2, varscan2
- EXTL1 | c.559G>T p.V187L | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs151111615; called by muse, mutect2, varscan2
- EXTL1 | c.560T>C p.V187A | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.038); catalogued as COSV100959090; called by muse, mutect2, varscan2
- FPR3 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 181/484 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.078); catalogued as COSV59330817; called by muse, mutect2, varscan2
- GABRA4 | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51931158; called by muse, mutect2, varscan2
- HLA-G | c.617C>G p.A206G | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.09); catalogued as COSV64406376; called by muse, mutect2
- KLF5 | c.398G>T p.S133I | Missense Mutation (SNP) | VAF 75/183 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV66614904; called by muse, mutect2, varscan2
- KMT2E | c.2716A>C p.M906L | Missense Mutation (SNP) | VAF 110/299 reads (37%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV57576317; called by muse, mutect2, varscan2
- KRT3 | c.1019A>G p.D340G | Missense Mutation (SNP) | VAF 184/422 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV58816238; called by muse, mutect2, varscan2
- MAGEB3 | c.628G>T p.V210L | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV100854824, COSV64397409; called by muse, mutect2, varscan2
- MAP1S | c.2444G>T p.G815V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV60723481; called by muse, mutect2, varscan2
- MARCHF1 | c.242+1G>A p.X81_splice (on ENST00000274056; = p.X64_splice on NM_017923.4) | Splice Site (SNP) | VAF 60/158 reads (38%) | catalogued as COSV56822185; called by muse, mutect2, varscan2
- MCF2L | c.2117G>A p.C706Y (on ENST00000375608; = p.C674Y on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0.02); catalogued as COSV56179446; called by muse, mutect2, varscan2
- MMRN2 | c.812A>G p.Q271R | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV64400962; called by muse, mutect2, varscan2
- NCKIPSD | c.1793-2A>T p.X598_splice | Splice Site (SNP) | VAF 9/98 reads (9%) | catalogued as COSV99583848; called by muse, mutect2
- NOTCH4 | c.2577C>A p.C859* | Nonsense Mutation (SNP) | VAF 140/398 reads (35%) | catalogued as COSV66682170; called by muse, mutect2, varscan2
- PGLYRP3 | c.44T>C p.L15P | Missense Mutation (SNP) | VAF 328/844 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV51951359; called by muse, mutect2, varscan2
- RASGRP3 | c.1866G>C p.E622D (on ENST00000402538 / NM_001349975.2; = p.E621D on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.005); catalogued as COSV67823258; called by muse, mutect2, varscan2
- RELN | c.3648C>G p.D1216E | Missense Mutation (SNP) | VAF 151/393 reads (38%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.97); catalogued as COSV59016648; called by muse, mutect2, varscan2
- SLC2A2 | c.1388C>T p.P463L | Missense Mutation (SNP) | VAF 68/263 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV58587271; called by muse, mutect2, varscan2
- SLC5A7 | c.1066A>C p.S356R | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50895207; called by muse, mutect2, varscan2
- ST3GAL1 | c.177C>G p.C59W | Missense Mutation (SNP) | VAF 38/118 reads (32%) | PolyPhen probably damaging (1); catalogued as COSV100171970; called by muse, mutect2
- TTN | c.4111G>A p.G1371R (on ENST00000591111; = p.G1325R on NM_003319.4) | Missense Mutation (SNP) | VAF 40/100 reads (40%) | PolyPhen probably damaging (1); catalogued as rs267599091, COSV60179757; called by muse, mutect2, varscan2
- WNK3 | c.271_302del p.D91Tfs*4 | Frame Shift Del (DEL) | VAF 58/304 reads (19%) | catalogued as COSV63614943; called by mutect2, pindel
- ADGRF5 | c.2173_2189del p.I725Dfs*3 | Frame Shift Del (DEL) | VAF 133/458 reads (29%) | called by mutect2, pindel, varscan2
- GNRHR | c.263_287del p.L88Hfs*25 | Frame Shift Del (DEL) | VAF 48/234 reads (21%) | called by mutect2, pindel, varscan2
- IGHV3OR16-8 | c.276C>A p.D92E | Missense Mutation (SNP) | VAF 26/773 reads (3%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.187); called by muse, mutect2
- KDR | c.2851_2853del p.Y951del | In Frame Del (DEL) | VAF 99/262 reads (38%) | called by mutect2, pindel, varscan2
- LUZP4 | c.233_282del p.R78Kfs*19 | Frame Shift Del (DEL) | VAF 126/545 reads (23%) | called by mutect2, pindel
- MARVELD3 | c.514_560del p.R172Mfs*61 | Frame Shift Del (DEL) | VAF 26/112 reads (23%) | called by mutect2, pindel
- ACSL4 | c.1890A>G p.K630= (on ENST00000340800 / NM_022977.2; = p.K589= on NM_004458.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 131/337 reads (39%) | catalogued as COSV61614794; called by muse, mutect2, varscan2
- ADAMTS17 | c.1944G>A p.V648= | Silent (SNP) | VAF 15/21 reads (71%) | catalogued as rs758168839, COSV99170498; called by muse, mutect2, varscan2
- ALB | c.1108C>T p.L370= | Silent (SNP) | VAF 94/271 reads (35%) | catalogued as COSV99891185; called by muse, mutect2, varscan2
- AMHR2 | c.372T>G p.P124= | Silent (SNP) | VAF 72/160 reads (45%) | catalogued as COSV57686284; called by muse, mutect2, varscan2
- ANK3 | c.6573T>A p.P2191= | Silent (SNP) | VAF 117/299 reads (39%) | catalogued as COSV55067951; called by muse, mutect2, varscan2
- KIAA1210 | c.4494C>T p.T1498= | Silent (SNP) | VAF 73/168 reads (43%) | catalogued as COSV68178340; called by muse, mutect2, varscan2
- NTAQ1 | c.96T>A p.I32= | Silent (SNP) | VAF 85/305 reads (28%) | catalogued as COSV54875313; called by muse, mutect2, varscan2
- SMC1A | c.3429C>A p.A1143= | Silent (SNP) | VAF 52/126 reads (41%) | catalogued as COSV59130349; called by muse, mutect2, varscan2
- SMC6 | c.1782T>C p.D594= | Silent (SNP) | VAF 64/198 reads (32%) | catalogued as COSV61176202; called by muse, mutect2, varscan2
- SYNE2 | c.2388A>G p.Q796= | Silent (SNP) | VAF 165/459 reads (36%) | catalogued as COSV59958034; called by muse, mutect2, varscan2
- TCP11L2 | c.48C>T p.S16= | Silent (SNP) | VAF 53/74 reads (72%) | catalogued as COSV54431196; called by muse, mutect2, varscan2
- TEAD2 | c.345C>A p.I115= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV60874074; called by muse, mutect2, varscan2
- AFDN | chr6:167826013 A>T | 5'Flank (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- DCHS2 | n.2781C>A | RNA (SNP) | VAF 108/269 reads (40%) | catalogued as COSV100251486, COSV59739598; called by muse, mutect2, varscan2
